Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A3SY, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A3SY-01A (Primary Tumor).

[page 1 of 2]
LABORATORY MEDICINE PROGRAM

Surgical Pathology Consultation Report

Specimen(s) Received

1. Thyroid: Right Lobe

PW TSS on 2/2013, TCGA tumor 15

100% follicular variant. *hu*

Diagnosis

Papillary carcinoma, oncocytic variant 1.4 cm, right: Thyroid, right hemithyroidectomy specimen.

Comment

This case has been seen in consultation with Dr. and he agrees with the interpretation and diagnosis.

Synoptic Data

Procedure: Right hemithyroidectomy
Received: Fresh
Specimen Integrity: Intact
Specimen Size: Right lobe:
3.4 cm
2.5 cm
1.5 cm
Isthmus +/- pyramidal lobe:
1.5 cm
0.2 cm
0.2 cm
Specimen Weight: 7.1 g
Tumor Focality: Unifocal

----- DOMINANT TUMOR -----

Tumor Laterality: Right lobe
Tumor Size: Greatest dimension: 1.4cm
Additional dimension: 1.3 cm
Additional dimension: 1.2 cm
Histologic Type: Papillary carcinoma, oncocytic or oxyphilic variant
Follicular architecture
Solid architecture
Oncocytic or oxyphilic cytomorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Tumor Capsule: Totally encapsulated
Tumor Capsular Invasion: Present, extent minimal

ICD-O-3
CQCF: Carcinoma, papillary, follicular variant
8340/3

Rxn: carcinoma, papillary
oxyphilic cell
8342/3

Site: thyroid, NOS
C73.9

4-312
ED

[page 2 of 2]
Surgical Pathology Consultation Report

Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified
TNM Descriptors: Not applicable
Primary Tumor (pT): pT1b: Tumor more than 1 cm but not more than 2 cm in greatest dimension, limited to the thyroid
Regional Lymph Nodes (pN): pNX: Regional lymph nodes cannot be assigned
Number of regional lymph nodes examined: 0
Number of regional lymph nodes involved: 0
Distant Metastasis (pM): Not applicable
Additional Pathologic Findings: None Identified

*Pathologic Staging is based on AJCC/UICC TNM, Edition

Electronically verified by:

Clinical History

STITCH MARKS UPPER POLE

Gross Description

1. The specimen labeled with the patient's name and as "right lobe", consists of a right hemithyroidectomy specimen that is oriented with a stitch at the upper pole and weighs 7.1 g. The lobe measures 3.4 cm SI x 2.5 cm ML x 1.5 cm AP and the isthmus measures 1.5 SI x 0.2 cm ML x 0.2 cm AP. The external surfaces have fibrous adhesions and are painted with liquid bluing. No parathyroid glands and/or lymph nodes are identified grossly. The lower pole contains one delineated nodule(s) that measure 1.4 cm SI x 1.3 cm ML x 1.2 cm AP. The remainder of the thyroid tissue is grossly normal. Sections of nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:
1A-G specimen submitted, superior to inferior

Source: NCI Genomic Data Commons file 931f0a81-393f-48a9-87d2-b72a81382cd7 (TCGA-EM-A3SY.D989DFCB-64F0-48A5-A70C-B1D8B9044417.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).